Somatic mutation profile of tumor specimen ALCH-B3E7-TTP1-A (aliquot ALCH-B3E7-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3E7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.5 years (25,765 days).
Specimen ALCH-B3E7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d7d456d-ee09-4450-8155-73c69660a4a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3E7-NB1-A (Blood Derived Normal), aliquot ALCH-B3E7-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d283536-c0ff-44f1-a4f9-5e71f0dc64a3

The open-access MAF lists 777 somatic variants for this specimen: 535 protein-altering or splice-affecting, 155 silent, 87 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 447, Silent 155, Intron 36, Nonsense Mutation 36, RNA 24, Splice Site 20, Frame Shift Del 18, 5'UTR 12, 3'UTR 8, Frame Shift Ins 5, 3'Flank 4, Splice Region 4.

Variants (750 of 777; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXG1 | c.460del p.E154Rfs*38 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as rs398124204; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NFE2L2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 161/842 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.675G>T p.R225S | Missense Mutation (SNP) | VAF 54/422 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as COSV52742772; called by muse, mutect2, varscan2
- ACR | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53361696; called by muse, mutect2, varscan2
- ADORA2A | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 64/319 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.137); catalogued as rs4990; called by muse, mutect2, varscan2
- AMPD1 | c.1672T>A p.S558T | Missense Mutation (SNP) | VAF 70/310 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV62417939; called by muse, mutect2, varscan2
- ANK3 | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55066154, COSV55073928; called by muse, mutect2, varscan2
- AOX1 | c.2782G>T p.A928S | Missense Mutation (SNP) | VAF 66/304 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV65979820; called by muse, mutect2, varscan2
- AP002512.3 | c.16G>T p.D6Y | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.05); catalogued as COSV56565765; called by muse, mutect2, varscan2
- ASB10 | c.206G>A p.C69Y | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.185); catalogued as rs1368423332; called by muse, mutect2
- ASTN1 | c.1451G>T p.C484F | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56079543; called by muse, mutect2, varscan2
- ATG9A | c.1672A>G p.M558V | Missense Mutation (SNP) | VAF 118/505 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs751803718; called by muse, mutect2, varscan2
- ATP2B3 | c.1978G>T p.D660Y | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1428385982, COSV54840464; called by muse, mutect2, varscan2
- ATXN1 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 20/238 reads (8%) | catalogued as COSV55216644; called by muse, mutect2
- BDP1 | c.3040G>C p.A1014P | Missense Mutation (SNP) | VAF 50/333 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as COSV62432953; called by muse, mutect2, varscan2
- BICD1 | c.1005+1G>C p.X335_splice | Splice Site (SNP) | VAF 7/56 reads (13%) | catalogued as COSV55684551; called by muse, mutect2, varscan2
- C6 | c.1286A>G p.H429R | Missense Mutation (SNP) | VAF 88/675 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as rs966459511; called by muse, mutect2, varscan2
- CADPS2 | c.2051A>G p.Y684C | Missense Mutation (SNP) | VAF 81/343 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57380164; called by muse, mutect2, varscan2
- CASR | c.2853G>T p.Q951H (on ENST00000490131; = p.Q1028H on NM_000388.4) | Missense Mutation (SNP) | VAF 45/289 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.176); catalogued as COSV99949061; called by muse, mutect2, varscan2
- CCDC148 | c.783A>T p.E261D | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV51768783; called by muse, mutect2, varscan2
- CCDC57 | c.594C>A p.N198K | Missense Mutation (SNP) | VAF 102/543 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV66434120; called by muse, mutect2, varscan2
- CD22 | c.938A>G p.N313S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs765592700; called by muse, mutect2, varscan2
- CDH18 | c.2243G>T p.G748V | Missense Mutation (SNP) | VAF 48/615 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as COSV56913662; called by muse, mutect2
- CFAP53 | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 207/826 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1300811287, COSV101275012; called by muse, mutect2, varscan2
- CFHR4 | c.245C>A p.P82Q (on ENST00000367416 / NM_001201551.2; = p.P83Q on NM_006684.5) | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.888); catalogued as COSV52229877; called by muse, mutect2, varscan2
- COL7A1 | c.1721G>T p.R574L | Missense Mutation (SNP) | VAF 153/498 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV100097637; called by muse, mutect2, varscan2
- COL9A1 | c.911del p.P304Rfs*24 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as COSV57893213; called by mutect2, pindel, varscan2
- CPS1 | c.1291G>C p.G431R | Missense Mutation (SNP) | VAF 56/742 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM114318; called by muse, mutect2
- CPXM2 | c.1983C>G p.I661M | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs901974839; called by muse, mutect2, varscan2
- CSMD1 | c.9331G>T p.G3111* (on ENST00000520002; = p.G3110* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 61/242 reads (25%) | catalogued as COSV59282362; called by muse, mutect2, varscan2
- CSMD1 | c.9330G>T p.E3110D (on ENST00000520002; = p.E3109D on NM_033225.6) | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.987); catalogued as COSV59377721; called by muse, varscan2
- CUBN | c.1277G>T p.G426V | Missense Mutation (SNP) | VAF 98/546 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs752890030; called by muse, mutect2, varscan2
- CUX2 | c.2225C>G p.P742R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV55645550; called by muse, mutect2, varscan2
- DLK1 | c.65A>G p.Y22C | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.145); catalogued as rs368931929; called by mutect2, varscan2
- DMD | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 192/515 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs772546251, COSV55899047; called by muse, mutect2, varscan2
- DMXL1 | c.4921A>G p.I1641V | Missense Mutation (SNP) | VAF 57/460 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs376883962; called by muse, mutect2, varscan2
- DNAH7 | c.9528G>T p.K3176N | Missense Mutation (SNP) | VAF 45/461 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56781978; called by muse, mutect2, varscan2
- DNAJC30 | c.20G>T p.R7L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782676844; called by muse, mutect2, varscan2
- DOCK2 | c.1394G>T p.C465F | Missense Mutation (SNP) | VAF 55/358 reads (15%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.967); catalogued as COSV56957588; called by muse, mutect2, varscan2
- DOP1A | c.3893C>G p.P1298R | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99380607; called by muse, mutect2, varscan2
- DPP10 | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100059334; called by muse, mutect2, varscan2
- ELMOD1 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV56195725; called by muse, mutect2, varscan2
- FAM193B | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs771557996; called by muse, mutect2, varscan2
- FBN2 | c.8550del p.N2851Mfs*46 | Frame Shift Del (DEL) | VAF 44/322 reads (14%) | catalogued as COSV99326276; called by mutect2, pindel, varscan2
- FFAR1 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 42/422 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.27); catalogued as rs1248094844; called by muse, mutect2, varscan2
- FGFR1 | c.841A>T p.S281C (on ENST00000447712 / NM_023110.3; = p.S279C on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as CM133776; called by muse, mutect2, varscan2
- FLG2 | c.1223C>G p.S408C | Missense Mutation (SNP) | VAF 88/268 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV66167681; called by muse, varscan2
- FSCB | c.440del p.P147Lfs*2 | Frame Shift Del (DEL) | VAF 50/381 reads (13%) | catalogued as COSV61219806; called by mutect2, pindel, varscan2
- GATC | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.489); catalogued as COSV99985076; called by muse, mutect2, varscan2
- GFRAL | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 45/364 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as COSV61231407, COSV61232771; called by muse, mutect2, varscan2
- GMDS | c.103-1G>T p.X35_splice | Splice Site (SNP) | VAF 63/371 reads (17%) | catalogued as COSV66439639; called by muse, mutect2, varscan2
- HAS1 | c.1178G>T p.W393L | Missense Mutation (SNP) | VAF 56/269 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.434); catalogued as COSV55787737; called by muse, mutect2, varscan2
- HAS1 | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.041); catalogued as COSV55787334; called by muse, mutect2, varscan2
- HIP1 | c.2943G>A p.M981I | Missense Mutation (SNP) | VAF 51/286 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV61187144; called by muse, varscan2
- IGDCC3 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs754726071, COSV60076221, COSV60078105; called by muse, mutect2, varscan2
- IGHV1-58 | c.149G>A p.S50N | Missense Mutation (SNP) | VAF 107/663 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs375611539; called by muse, mutect2, varscan2
- JAKMIP1 | c.484C>G p.R162G | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV51526406; called by muse, mutect2, varscan2
- KANSL2 | c.382G>T p.G128W | Missense Mutation (SNP) | VAF 72/322 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs781702090; called by muse, mutect2, varscan2
- KATNAL2 | c.1166G>T p.R389L (on ENST00000356157 / NM_001353899.1; = p.R317L on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/364 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs566442595; called by muse, varscan2
- KDM5A | c.3379-2A>T p.X1127_splice | Splice Site (SNP) | VAF 54/444 reads (12%) | catalogued as COSV66992031; called by muse, mutect2, varscan2
- KLHL4 | c.1358C>A p.T453N | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV64147682; called by muse, mutect2, varscan2
- KMT2A | c.1277G>T p.R426L | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.268); catalogued as COSV100628114, COSV63282866; called by muse, mutect2, varscan2
- LCE1E | c.5C>A p.S2Y | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100908561; called by muse, varscan2
- LEPR | c.3102G>C p.Q1034H | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV62748506; called by muse, mutect2
- LRP1B | c.3685G>A p.E1229K | Missense Mutation (SNP) | VAF 93/561 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.985); catalogued as COSV67284991; called by muse, mutect2, varscan2
- LRP2 | c.6617G>C p.W2206S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55584045; called by muse, mutect2, varscan2
- LRRC30 | c.478del p.A160Pfs*6 | Frame Shift Del (DEL) | VAF 33/185 reads (18%) | catalogued as COSV67302395; called by mutect2, pindel, varscan2
- LRRIQ4 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61620505; called by mutect2, varscan2
- LVRN | c.295C>G p.P99A | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63497634; called by muse, mutect2, varscan2
- LYSMD4 | c.806G>A p.G269E (on ENST00000409796 / NM_001284417.2; = p.G270E on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/383 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as rs1270983162; called by muse, mutect2, varscan2
- MACO1 | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.627); catalogued as COSV65475108; called by muse, mutect2, varscan2
- MALRD1 | c.2656A>T p.R886W | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as rs1220419979; called by muse, mutect2, varscan2
- MAP3K19 | c.280C>A p.Q94K | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.339); catalogued as COSV59639008; called by muse, mutect2, varscan2
- MARCHF1 | c.539C>G p.T180R (on ENST00000274056; = p.T163R on NM_017923.4) | Missense Mutation (SNP) | VAF 62/303 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1250065471, COSV56821776; called by muse, mutect2, varscan2
- MGAM2 | c.2000C>T p.T667I | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1275574502; called by muse, mutect2
- MORC1 | c.237C>A p.D79E | Missense Mutation (SNP) | VAF 96/1428 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV99225263; called by muse, mutect2
- MSLN | c.1230G>T p.Q410H | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV99558308; called by muse, mutect2, varscan2
- MUC16 | c.30931G>T p.G10311C | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV67486815; called by muse, mutect2, varscan2
- MUC5B | c.6446C>A p.P2149H | Missense Mutation (SNP) | VAF 170/472 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.192); catalogued as rs199736721; called by muse, varscan2
- NCOR1 | c.3113C>T p.P1038L | Missense Mutation (SNP) | VAF 55/476 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV51988368, COSV51999724; called by muse, mutect2, varscan2
- NELL2 | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 54/387 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV61581552; called by muse, mutect2, varscan2
- NHSL2 | c.34C>A p.R12S | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.995); catalogued as rs756078762; called by mutect2, varscan2
- NIM1K | c.883T>A p.S295T | Missense Mutation (SNP) | VAF 43/336 reads (13%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.976); catalogued as rs1366141312; called by muse, mutect2, varscan2
- NLRX1 | c.1371C>G p.I457M | Missense Mutation (SNP) | VAF 60/312 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52702390, COSV52705267; called by muse, mutect2, varscan2
- NRAP | c.4007G>T p.R1336L (on ENST00000359988 / NM_001322945.2; = p.R1301L on NM_006175.4) | Missense Mutation (SNP) | VAF 84/293 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV100748616; called by muse, mutect2, varscan2
- NRXN2 | c.2726G>T p.R909L | Missense Mutation (SNP) | VAF 59/267 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs778338151; called by muse, mutect2, varscan2
- NSMAF | c.297-1G>C p.X99_splice | Splice Site (SNP) | VAF 44/401 reads (11%) | catalogued as COSV50702260; called by muse, mutect2, varscan2
- NTM | c.69C>A p.F23L | Missense Mutation (SNP) | VAF 10/269 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as rs1565718356, COSV100868677; called by muse, mutect2
- NXPH3 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 56/356 reads (16%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.809); catalogued as rs758345082, COSV60872795; called by muse, mutect2, varscan2
- OGFOD3 | c.901A>G p.I301V | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as rs765089479; called by muse, mutect2, varscan2
- OR1C1 | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 102/282 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV68715454; called by muse, mutect2, varscan2
- OR2T4 | c.329T>A p.V110E | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV63543646; called by muse, mutect2, varscan2
- OR51A7 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 60/297 reads (20%) | catalogued as COSV100834604; called by muse, mutect2, varscan2
- OR51I2 | c.25C>A p.P9T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as COSV100413425; called by mutect2, varscan2
- OR52J3 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 46/327 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs774802089, COSV66747273; called by muse, mutect2, varscan2
- OR5I1 | c.597G>T p.W199C | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1303966058; called by muse, mutect2, varscan2
- PCDHA3 | c.1748G>T p.R583L | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.088); catalogued as rs782172179, COSV63539931; called by muse, mutect2, varscan2
- PCDHA6 | c.517A>C p.S173R | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.484); catalogued as COSV65353845; called by muse, mutect2, varscan2
- PCDHGA3 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as COSV53910106; called by muse, mutect2, varscan2
- PCDHGA5 | c.744C>A p.S248R | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV53915020; called by muse, varscan2
- PCLO | c.4957A>T p.S1653C | Missense Mutation (SNP) | VAF 37/298 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1358207733; called by muse, mutect2, varscan2
- PGK2 | c.477C>A p.D159E | Missense Mutation (SNP) | VAF 59/363 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV100505402; called by muse, mutect2, varscan2
- PHLDB3 | c.1195G>T p.G399W | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs569511306; called by muse, mutect2, varscan2
- PKHD1L1 | c.7090T>A p.Y2364N | Missense Mutation (SNP) | VAF 135/542 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV65742846; called by muse, mutect2, varscan2
- PLSCR5 | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71649135; called by muse, mutect2, varscan2
- PNOC | c.260C>A p.P87Q | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs753670435, COSV100108468; called by muse, mutect2, varscan2
- PPFIBP1 | c.2784G>T p.M928I (on ENST00000318304 / NM_177444.3; = p.M922I on NM_003622.4) | Missense Mutation (SNP) | VAF 82/424 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as rs1212435678; called by muse, mutect2, varscan2
- PRSS35 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 130/550 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63800459; called by muse, mutect2, varscan2
- PZP | c.2201C>A p.P734H | Missense Mutation (SNP) | VAF 89/432 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.396); catalogued as COSV99735422; called by muse, mutect2, varscan2
- RAD51 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 46/855 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV99139189; called by muse, mutect2
- RIMBP2 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 69/231 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs770003929, COSV55476117; called by muse, mutect2, varscan2
- RNASEH2A | c.874G>T p.G292C | Missense Mutation (SNP) | VAF 131/579 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV99677436; called by muse, mutect2, varscan2
- RUNX1T1 | c.1031G>T p.R344I (on ENST00000265814 / NM_001198628.1; = p.R317I on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/718 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56161087; called by muse, mutect2
- RYR2 | c.11062T>C p.Y3688H | Missense Mutation (SNP) | VAF 204/636 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99053471; called by muse, mutect2, varscan2
- SCAPER | c.3691C>G p.L1231V | Missense Mutation (SNP) | VAF 88/389 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57755585; called by muse, mutect2, varscan2
- SCN2A | c.3559G>T p.E1187* | Nonsense Mutation (SNP) | VAF 155/670 reads (23%) | catalogued as rs1553590143; called by muse, mutect2, varscan2
- SDK1 | c.5486A>G p.N1829S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1241696794; called by muse, mutect2, varscan2
- SEC14L3 | c.149A>T p.Q50L | Missense Mutation (SNP) | VAF 36/488 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs1463778835; called by muse, mutect2
- SHISAL1 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.294); catalogued as COSV66988691; called by muse, mutect2, varscan2
- SI | c.4829C>A p.P1610H | Missense Mutation (SNP) | VAF 171/1174 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773851366, COSV52277886; called by muse, mutect2, varscan2
- SLC25A15 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 143/810 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.143); catalogued as rs753073964; called by muse, mutect2, varscan2
- SLC2A13 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.022); catalogued as rs1402944975; called by muse, mutect2, varscan2
- SLC39A5 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs922870649; called by muse, mutect2, varscan2
- SLC6A19 | c.1282G>T p.G428W | Missense Mutation (SNP) | VAF 113/544 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58675306; called by muse, mutect2, varscan2
- SMARCE1 | c.157-2A>G p.X53_splice | Splice Site (SNP) | VAF 78/299 reads (26%) | catalogued as COSV100796029; called by muse, mutect2, varscan2
- SON | c.3836G>T p.R1279I | Missense Mutation (SNP) | VAF 54/303 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); catalogued as rs145125297; called by muse, mutect2, varscan2
- SRSF6 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as COSV99719855; called by muse, mutect2, varscan2
- SUGT1 | c.328+1G>C p.X110_splice | Splice Site (SNP) | VAF 14/84 reads (17%) | catalogued as COSV100139476; called by muse, mutect2, varscan2
- SUPT16H | c.1826G>T p.G609V | Missense Mutation (SNP) | VAF 83/469 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99360133; called by muse, mutect2, varscan2
- TDRD15 | c.4630G>T p.V1544L | Missense Mutation (SNP) | VAF 86/275 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs1044613953; called by muse, mutect2, varscan2
- TLR4 | c.1027G>A p.G343R (on ENST00000355622 / NM_138554.5; = p.G303R on NM_003266.4) | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1467722104; called by muse, varscan2
- TMEM132D | c.2242G>T p.D748Y | Missense Mutation (SNP) | VAF 58/698 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV67160163; called by muse, mutect2
- TMEM214 | c.1043G>T p.R348L | Missense Mutation (SNP) | VAF 116/368 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV53193175; called by muse, mutect2, varscan2
- TP53 | c.142del p.D48Tfs*75 | Frame Shift Del (DEL) | VAF 35/181 reads (19%) | catalogued as CD114001, COSV52987957, COSV53821134; called by mutect2, pindel, varscan2
- TSHZ1 | c.1063del p.A355Rfs*22 (on ENST00000580243 / NM_001308210.2; = p.A310Rfs*22 on NM_005786.6) | Frame Shift Del (DEL) | VAF 47/137 reads (34%) | catalogued as COSV59011898; called by mutect2, pindel, varscan2
- TTC28 | c.1705G>T p.A569S | Missense Mutation (SNP) | VAF 108/335 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.574); catalogued as rs1159581730; called by muse, mutect2, varscan2
- TTN | c.97232G>A p.R32411Q (on ENST00000591111; = p.R24987Q on NM_003319.4) | Missense Mutation (SNP) | VAF 46/495 reads (9%) | PolyPhen probably damaging (0.992); catalogued as rs369245991; ClinVar: uncertain significance; called by muse, mutect2
- UBLCP1 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 56/634 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV57144793; called by muse, mutect2
- UBN2 | c.3574A>G p.T1192A | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.01); catalogued as rs762496451; called by muse, mutect2, varscan2
- UNC45B | c.1343C>A p.A448D | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52095995; called by muse, mutect2, varscan2
- UNC80 | c.3250G>T p.G1084C | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV55894105; called by muse, mutect2, varscan2
- VIT | c.151G>C p.G51R | Missense Mutation (SNP) | VAF 114/316 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV64895864; called by muse, varscan2
- WDFY1 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51794019; called by muse, mutect2, varscan2
- ZHX2 | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779230167, COSV58710468; called by muse, mutect2, varscan2
- ZNF208 | c.3167C>A p.P1056H | Missense Mutation (SNP) | VAF 42/688 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs1005747789, COSV68108324; called by muse, mutect2
- ZNF302 | c.511G>T p.D171Y (on ENST00000627982; = p.D92Y on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs747338814; called by muse, mutect2, varscan2
- ZNF415 | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs753872090, COSV54700684; called by muse, mutect2, varscan2
- ZNF444 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs979752786; called by muse, mutect2, varscan2
- ZNF536 | c.81C>A p.N27K | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV62824162; called by muse, mutect2, varscan2
- ZNF536 | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs761077464; called by muse, mutect2, varscan2
- ZNF559 | c.143A>G p.K48R | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.46); catalogued as rs1431289335; called by muse, mutect2
- ZNF639 | c.695C>G p.S232* | Nonsense Mutation (SNP) | VAF 67/545 reads (12%) | catalogued as rs1230567968; called by muse, mutect2, varscan2
- ZNF716 | c.1381G>T p.E461* | Nonsense Mutation (SNP) | VAF 35/441 reads (8%) | catalogued as rs1192695901, COSV70781145; called by muse, mutect2
- ZNF831 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100926014, COSV64038265; called by muse, mutect2, varscan2
- ZNF883 | c.853A>T p.K285* | Nonsense Mutation (SNP) | VAF 60/232 reads (26%) | catalogued as rs368914427, COSV71308927; called by muse, mutect2, varscan2
- ZNF98 | c.510C>G p.N170K | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV63335785; called by muse, mutect2, varscan2
- ZRSR2 | c.19A>G p.M7V | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV57067542; called by muse, mutect2, varscan2
- ZSCAN5B | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 62/332 reads (19%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.989); catalogued as COSV100748615; called by muse, mutect2, varscan2
- ABCA2 | c.5890G>T p.D1964Y (on ENST00000614293; = p.D1934Y on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ABCC5 | c.2933A>T p.D978V | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCC5 | c.2932G>T p.D978Y | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCC6 | c.674G>T p.R225M | Missense Mutation (SNP) | VAF 52/414 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- ACSF2 | c.1173G>T p.L391F | Missense Mutation (SNP) | VAF 106/590 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ACSM2B | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ACSM5 | c.361del p.V121Yfs*21 | Frame Shift Del (DEL) | VAF 26/131 reads (20%) | called by mutect2, pindel, varscan2
- ACTL9 | c.743T>A p.L248Q | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); called by muse, mutect2
- ACVR1B | c.1051A>T p.I351L | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ADAM23 | c.1730C>A p.S577Y | Missense Mutation (SNP) | VAF 48/548 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS17 | c.635G>T p.W212L | Missense Mutation (SNP) | VAF 129/433 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS6 | c.2706-2A>G p.X902_splice | Splice Site (SNP) | VAF 14/183 reads (8%) | called by muse, mutect2
- ADAMTS6 | c.902G>T p.R301L | Missense Mutation (SNP) | VAF 40/366 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRB3 | c.4264C>A p.L1422I | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADGRV1 | c.1690G>T p.A564S | Missense Mutation (SNP) | VAF 48/553 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- ADGRV1 | c.12878G>T p.G4293V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRV1 | c.16748C>A p.P5583Q | Missense Mutation (SNP) | VAF 51/467 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKT3 | c.370C>A p.Q124K | Missense Mutation (SNP) | VAF 86/312 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALMS1 | c.7541-2A>T p.X2514_splice | Splice Site (SNP) | VAF 38/602 reads (6%) | called by muse, mutect2
- AMOTL1 | c.1679T>G p.L560* | Nonsense Mutation (SNP) | VAF 49/244 reads (20%) | called by muse, mutect2, varscan2
- AMPH | c.1241T>A p.M414K | Missense Mutation (SNP) | VAF 89/451 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- AMPH | c.206-1G>T p.X69_splice | Splice Site (SNP) | VAF 38/359 reads (11%) | called by muse, mutect2, varscan2
- ANK2 | c.6342G>T p.K2114N | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- ANKRD36 | c.2795A>T p.D932V | Missense Mutation (SNP) | VAF 68/926 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- APC | c.2214G>T p.K738N | Missense Mutation (SNP) | VAF 51/369 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- ARAP3 | c.1423G>T p.A475S | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ARHGEF15 | c.1205T>C p.V402A | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- ARID3C | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ARSF | c.1192A>G p.K398E | Missense Mutation (SNP) | VAF 76/247 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASCC3 | c.4105A>T p.K1369* | Nonsense Mutation (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- ATAD2B | c.1912A>G p.K638E | Missense Mutation (SNP) | VAF 159/514 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP13A4 | c.2770-2A>T p.X924_splice | Splice Site (SNP) | VAF 145/1199 reads (12%) | called by muse, mutect2, varscan2
- ATP4A | c.157-5C>A | Splice Region (SNP) | VAF 20/266 reads (8%) | called by muse, mutect2
- BARHL2 | c.1100C>A p.P367H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- BAZ2A | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 163/649 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- BDP1 | c.3912G>C p.K1304N | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BDP1 | c.3913G>T p.V1305L | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by mutect2, varscan2
- BEND2 | c.2284A>T p.R762* | Nonsense Mutation (SNP) | VAF 159/367 reads (43%) | called by muse, mutect2, varscan2
- BPNT2 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 84/415 reads (20%) | called by muse, mutect2, varscan2
- BSN | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- C15orf39 | c.1732G>T p.V578L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C1orf167 | c.1076C>A p.S359Y | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- C2CD6 | c.1234C>A p.L412M | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- C5orf15 | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2
- CACNA2D1 | c.2719G>T p.G907C (on ENST00000356253 / NM_001366867.1; = p.G895C on NM_000722.4) | Missense Mutation (SNP) | VAF 137/729 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- CALD1 | c.1321G>T p.G441* | Nonsense Mutation (SNP) | VAF 118/558 reads (21%) | called by muse, mutect2, varscan2
- CAMK2B | c.1885C>T p.Q629* | Nonsense Mutation (SNP) | VAF 67/287 reads (23%) | called by muse, mutect2, varscan2
- CAND1 | c.2494G>T p.D832Y | Missense Mutation (SNP) | VAF 29/505 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2
- CAND1 | c.3564A>T p.E1188D | Missense Mutation (SNP) | VAF 80/314 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- CAPRIN1 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 103/533 reads (19%) | called by muse, mutect2, varscan2
- CAPZA3 | c.194T>A p.I65N | Missense Mutation (SNP) | VAF 54/364 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- CARD6 | c.1427G>T p.S476I | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2
- CAVIN4 | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 169/916 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- CBLN4 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 56/269 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- CCDC33 | c.366G>T p.L122F | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); called by muse, mutect2
- CCDC60 | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 36/324 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- CCND2 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 54/437 reads (12%) | called by muse, mutect2, varscan2
- CCNI | c.278G>T p.S93I | Missense Mutation (SNP) | VAF 72/388 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CCT4 | c.1391C>A p.T464K | Missense Mutation (SNP) | VAF 269/898 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CD300C | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- CD4 | c.143G>T p.S48I | Missense Mutation (SNP) | VAF 66/386 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CD8A | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- CDADC1 | c.1088G>C p.G363A | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDC73 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 248/800 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CDH18 | c.2242G>T p.G748W | Missense Mutation (SNP) | VAF 50/620 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CDH19 | c.1139T>C p.F380S | Missense Mutation (SNP) | VAF 62/315 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEACAM8 | c.965T>A p.L322* | Nonsense Mutation (SNP) | VAF 116/555 reads (21%) | called by muse, mutect2, varscan2
- CELSR1 | c.6403G>C p.V2135L | Missense Mutation (SNP) | VAF 49/265 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CENPF | c.4410G>T p.E1470D | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CENPF | c.4411G>T p.G1471W | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CEP120 | c.1297A>T p.T433S | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CEP164 | c.2347G>C p.A783P | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- CEP57L1 | c.1288A>T p.T430S | Missense Mutation (SNP) | VAF 200/816 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP47 | c.1246G>T p.G416* | Nonsense Mutation (SNP) | VAF 95/289 reads (33%) | called by muse, mutect2, varscan2
- CFAP47 | c.1247G>T p.G416V | Missense Mutation (SNP) | VAF 97/293 reads (33%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CFAP47 | c.9365T>C p.M3122T | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- CHD8 | c.7089_7090del p.K2364Vfs*5 (on ENST00000646647 / NM_001170629.2; = p.K2085Vfs*5 on NM_020920.4) | Frame Shift Del (DEL) | VAF 71/439 reads (16%) | called by mutect2, pindel, varscan2
- CHD9 | c.5866G>A p.D1956N | Missense Mutation (SNP) | VAF 84/361 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CHGA | c.748C>G p.P250A | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, varscan2
- CHRNA1 | c.254C>A p.P85Q | Missense Mutation (SNP) | VAF 61/586 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2
- CILP | c.1633C>A p.L545M | Missense Mutation (SNP) | VAF 38/367 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CILP2 | c.3222G>T p.E1074D | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CKAP5 | c.1307dup p.L436Ffs*11 | Frame Shift Ins (INS) | VAF 28/266 reads (11%) | called by pindel, varscan2
- CKAP5 | c.1252C>G p.L418V | Missense Mutation (SNP) | VAF 49/375 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.906); called by muse, varscan2
- CNTN2 | c.2840A>C p.Y947S | Missense Mutation (SNP) | VAF 170/893 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CNTNAP4 | c.3511G>T p.V1171L | Missense Mutation (SNP) | VAF 59/227 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- CNTNAP5 | c.2960C>A p.S987* | Nonsense Mutation (SNP) | VAF 19/94 reads (20%) | called by muse, mutect2, varscan2
- COL11A2 | c.4057G>T p.V1353L (on ENST00000341947 / NM_080680.3; = p.V1246L on NM_080679.2) | Missense Mutation (SNP) | VAF 109/604 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- COL5A2 | c.2671G>C p.G891R | Missense Mutation (SNP) | VAF 64/1090 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL7A1 | c.6471G>T p.E2157D | Missense Mutation (SNP) | VAF 182/614 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, varscan2
- COLEC12 | c.611T>G p.M204R | Missense Mutation (SNP) | VAF 56/294 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CPNE4 | c.1200C>A p.S400R | Missense Mutation (SNP) | VAF 51/470 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CSMD1 | c.10108C>G p.Q3370E (on ENST00000520002; = p.Q3369E on NM_033225.6) | Missense Mutation (SNP) | VAF 55/281 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CSMD1 | c.4702C>G p.P1568A (on ENST00000520002; = p.P1567A on NM_033225.6) | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- CSMD3 | c.2009C>A p.P670H (on ENST00000297405 / NM_001363185.1; = p.P566H on NM_052900.3) | Missense Mutation (SNP) | VAF 139/570 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CTH | c.346+1G>T p.X116_splice | Splice Site (SNP) | VAF 163/614 reads (27%) | called by muse, mutect2, varscan2
- CUBN | c.1276G>T p.G426C | Missense Mutation (SNP) | VAF 98/547 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP3A43 | c.245T>A p.L82Q | Missense Mutation (SNP) | VAF 52/278 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DBR1 | c.796-1G>T p.X266_splice | Splice Site (SNP) | VAF 29/249 reads (12%) | called by muse, varscan2
- DCBLD2 | c.1720G>C p.G574R | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCSTAMP | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 144/793 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- DDX41 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2
- DEFB116 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 66/381 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DGKZ | c.44C>A p.S15Y | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.663); called by muse, mutect2
- DHX33 | c.1786A>G p.R596G | Missense Mutation (SNP) | VAF 77/311 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- DMRTA2 | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- DNAH2 | c.4586A>T p.H1529L | Missense Mutation (SNP) | VAF 68/329 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- DNAH3 | c.8676G>T p.E2892D | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- DNAH7 | c.4444G>C p.V1482L | Missense Mutation (SNP) | VAF 91/845 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH8 | c.2242C>G p.L748V | Missense Mutation (SNP) | VAF 87/418 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAJB8 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- DOC2B | c.636G>T p.L212= | Splice Region (SNP) | VAF 49/138 reads (36%) | called by muse, mutect2, varscan2
- DOCK2 | c.1151A>G p.K384R | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DOCK2 | c.2967G>A p.W989* | Nonsense Mutation (SNP) | VAF 29/296 reads (10%) | called by muse, mutect2, varscan2
- DPY19L2 | c.756A>T p.L252F | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- DPY19L3 | c.1181T>G p.L394R | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- DPYD | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- E2F7 | c.43A>T p.R15W | Missense Mutation (SNP) | VAF 46/695 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2
- EBLN1 | c.831T>A p.D277E | Missense Mutation (SNP) | VAF 83/380 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- EHBP1 | c.2677G>T p.A893S | Missense Mutation (SNP) | VAF 44/365 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- EHBP1L1 | c.2204G>T p.G735V | Missense Mutation (SNP) | VAF 87/284 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EIF4G1 | c.74dup p.Q27Afs*28 | Frame Shift Ins (INS) | VAF 80/596 reads (13%) | called by mutect2, pindel, varscan2
- ELFN2 | c.1668del p.K556Nfs*63 | Frame Shift Del (DEL) | VAF 108/362 reads (30%) | called by mutect2, pindel, varscan2
- ELFN2 | c.1474G>T p.D492Y | Missense Mutation (SNP) | VAF 20/271 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2
- ERC1 | c.110G>T p.S37I | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- EXOC3L2 | c.1264G>T p.V422F | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- FAM135A | c.3490T>G p.C1164G (on ENST00000370479 / NM_001351599.1; = p.C951G on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/354 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM136A | c.148G>C p.V50L | Missense Mutation (SNP) | VAF 90/323 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM155A | c.842A>T p.E281V | Missense Mutation (SNP) | VAF 71/280 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM47C | c.487G>C p.G163R | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- FAM47C | c.1579C>A p.P527T | Missense Mutation (SNP) | VAF 138/306 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.261); called by mutect2, varscan2
- FAN1 | c.1984G>T p.V662F | Missense Mutation (SNP) | VAF 78/434 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- FBLN7 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- FBN1 | c.3854A>C p.D1285A | Missense Mutation (SNP) | VAF 139/746 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- FBN2 | c.3899C>T p.T1300I | Missense Mutation (SNP) | VAF 96/745 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- FER | c.452A>G p.K151R | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2
- FGF6 | c.497A>T p.N166I | Missense Mutation (SNP) | VAF 89/422 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FIGNL1 | c.545_565del p.L182_Q189delins* | Nonsense Mutation (DEL) | VAF 41/239 reads (17%) | called by mutect2, pindel*, varscan2
- FLG2 | c.1262C>A p.S421Y | Missense Mutation (SNP) | VAF 123/429 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.099); called by muse, varscan2
- FMR1NB | c.482G>A p.C161Y | Missense Mutation (SNP) | VAF 99/297 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRMPD2 | c.2830A>T p.S944C | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- GALNT7 | c.1235G>T p.W412L | Missense Mutation (SNP) | VAF 123/554 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCKR | c.1492G>A p.G498S | Missense Mutation (SNP) | VAF 79/513 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- GLRA2 | c.607G>T p.E203* | Nonsense Mutation (SNP) | VAF 107/280 reads (38%) | called by muse, mutect2, varscan2
- GMIP | c.1985G>A p.S662N | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GMNN | c.389A>G p.E130G | Missense Mutation (SNP) | VAF 66/405 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GOLGA7B | c.139-2A>T p.X47_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | called by mutect2, varscan2
- GRAMD4 | c.1054T>G p.F352V | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- GSE1 | c.2323C>G p.L775V | Missense Mutation (SNP) | VAF 66/305 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GTF2I | c.860A>T p.E287V (on ENST00000573035 / NM_032999.4; = p.E267V on NM_001518.5) | Missense Mutation (SNP) | VAF 136/643 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GZMM | c.410A>T p.Q137L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.1); called by mutect2, varscan2
- HEATR6 | c.2090_2111del p.L697Qfs*2 | Frame Shift Del (DEL) | VAF 60/353 reads (17%) | called by mutect2, pindel
- HEPACAM | c.937C>A p.L313M | Missense Mutation (SNP) | VAF 48/642 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- HOXD1 | c.554C>A p.P185Q | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2
- HSCB | c.707A>T p.*236Lext*5 | Nonstop Mutation (SNP) | VAF 19/229 reads (8%) | called by muse, mutect2
- HSPBAP1 | c.506del p.G169Efs*59 | Frame Shift Del (DEL) | VAF 57/497 reads (11%) | called by mutect2, pindel, varscan2
- IGDCC3 | c.314C>A p.P105Q | Missense Mutation (SNP) | VAF 38/331 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGDCC3 | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 38/335 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGLL5 | c.538C>A p.L180M | Missense Mutation (SNP) | VAF 156/903 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGLV3-22 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 18/323 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.298); called by muse, mutect2
- IGSF11 | c.89G>T p.G30V (on ENST00000393775 / NM_001015887.3; = p.G29V on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- IKZF2 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IL17RE | c.367-2A>T p.X123_splice | Splice Site (SNP) | VAF 28/108 reads (26%) | called by muse, mutect2, varscan2
- IL1RAP | c.649C>G p.P217A | Missense Mutation (SNP) | VAF 150/745 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- IMPDH1 | c.170G>C p.R57P (on ENST00000470772 / NM_001142573.2; = p.R142P on NM_000883.4) | Missense Mutation (SNP) | VAF 65/588 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- IPO11 | c.1546C>G p.L516V | Missense Mutation (SNP) | VAF 38/336 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- ITGAM | c.1028G>T p.S343I | Missense Mutation (SNP) | VAF 74/318 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KATNIP | c.2202A>T p.Q734H | Missense Mutation (SNP) | VAF 80/460 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- KCNT1 | c.584T>A p.L195Q (on ENST00000488444; = p.L214Q on NM_020822.3) | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KCTD14 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- KHDRBS3 | c.810C>A p.D270E | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, varscan2
- KIAA0319 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 71/291 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIAA2012 | c.782C>A p.P261Q | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2
- KIF14 | c.4518A>T p.L1506F | Missense Mutation (SNP) | VAF 130/408 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIF20B | c.2194A>G p.I732V (on ENST00000371728 / NM_001284259.2; = p.I692V on NM_016195.4) | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- KIF26A | c.5003A>T p.E1668V | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- KIF26A | c.5504A>T p.E1835V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIF6 | c.1585T>A p.S529T | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLF10 | c.1190A>T p.K397M | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KLHL24 | c.371T>G p.V124G | Missense Mutation (SNP) | VAF 89/757 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- KMT2B | c.6266G>T p.G2089V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KMT2C | c.3388G>T p.G1130C | Missense Mutation (SNP) | VAF 37/442 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- KMT2D | c.11446G>T p.G3816* | Nonsense Mutation (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- KPNB1 | c.647A>T p.H216L | Missense Mutation (SNP) | VAF 124/767 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.229); called by muse, varscan2
- KPTN | c.1090A>G p.S364G | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- KRT23 | c.444C>G p.D148E | Missense Mutation (SNP) | VAF 79/388 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- L3MBTL1 | c.1054G>T p.E352* (on ENST00000418998 / NM_001377303.1; = p.E262* on NM_015478.7) | Nonsense Mutation (SNP) | VAF 74/239 reads (31%) | called by muse, mutect2, varscan2
- LAMB3 | c.892A>G p.N298D | Missense Mutation (SNP) | VAF 92/536 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- LGR5 | c.662G>C p.R221T | Missense Mutation (SNP) | VAF 102/466 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- LRFN2 | c.1552G>T p.D518Y | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- LRP1B | c.5501-1G>A p.X1834_splice | Splice Site (SNP) | VAF 22/423 reads (5%) | called by muse, mutect2
- LRRIQ4 | c.442G>T p.G148* | Nonsense Mutation (SNP) | VAF 26/95 reads (27%) | called by muse, mutect2, varscan2
- LYPD4 | c.566T>A p.M189K | Missense Mutation (SNP) | VAF 47/286 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- MAGEE1 | c.2657G>T p.S886I | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAGEL2 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- MAP2K2 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- MAST1 | c.1020T>A p.H340Q | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MBTPS2 | c.547C>G p.Q183E | Missense Mutation (SNP) | VAF 99/305 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- MCF2L2 | c.3280G>T p.A1094S | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2
- MEGF11 | c.2142C>A p.N714K | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2
- MEGF8 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MKNK1 | c.125del p.L42Cfs*14 | Frame Shift Del (DEL) | VAF 94/369 reads (25%) | called by mutect2, pindel, varscan2
- MPP6 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 19/286 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- MRPL10 | c.741G>T p.M247I | Missense Mutation (SNP) | VAF 59/410 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSR1 | c.60dup p.V21Cfs*4 | Frame Shift Ins (INS) | VAF 123/632 reads (19%) | called by mutect2, pindel, varscan2
- MUC16 | c.11827G>T p.A3943S | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYO1C | c.1401G>C p.A467= (on ENST00000648651 / NM_001080779.2; = p.A432= on NM_033375.5) | Splice Region (SNP) | VAF 53/279 reads (19%) | called by muse, mutect2, varscan2
- NAE1 | c.938A>T p.E313V | Missense Mutation (SNP) | VAF 90/313 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- NEBL | c.709A>T p.N237Y | Missense Mutation (SNP) | VAF 61/268 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- NEFH | c.960G>C p.E320D | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.203); called by muse, mutect2
- NEURL1B | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.181); called by muse, mutect2
- NGLY1 | c.639A>T p.R213S | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NKX2-5 | c.136T>A p.C46S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); called by muse, varscan2
- NLGN4X | c.1235G>T p.G412V | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NLRP14 | c.362-1G>T p.X121_splice | Splice Site (SNP) | VAF 41/333 reads (12%) | called by muse, mutect2, varscan2
- NLRP8 | c.1946T>A p.L649Q | Missense Mutation (SNP) | VAF 31/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRP1 | c.1984C>G p.H662D | Missense Mutation (SNP) | VAF 69/310 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NSMAF | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 44/399 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NWD1 | c.4302A>T p.R1434S | Missense Mutation (SNP) | VAF 82/411 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- OCA2 | c.2489dup p.A831Gfs*19 | Frame Shift Ins (INS) | VAF 175/1140 reads (15%) | called by mutect2, pindel, varscan2
- OLA1 | c.1084G>T p.V362F | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2
- OPRK1 | c.860G>T p.W287L | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2J2 | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- OR2T6 | c.537T>G p.C179W | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- OR4D6 | c.337T>A p.F113I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- OR4Q2 | c.493G>C p.V165L | Missense Mutation (SNP) | VAF 74/520 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR52R1 | c.719C>A p.A240D | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- OR5A1 | c.448G>T p.G150W | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- OR5AP2 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- OR5AP2 | c.19G>T p.V7F | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5AP2 | c.18G>T p.E6D | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5AU1 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 30/182 reads (16%) | called by muse, varscan2
- OR5AU1 | c.21C>A p.S7R | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, varscan2
- OR5M10 | c.680G>T p.R227M | Missense Mutation (SNP) | VAF 53/312 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- OR6C65 | c.854C>A p.P285H | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- OR7G1 | c.779T>C p.I260T | Missense Mutation (SNP) | VAF 103/403 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- OR8D2 | c.109del p.V37Sfs*9 | Frame Shift Del (DEL) | VAF 44/232 reads (19%) | called by mutect2, pindel, varscan2
- PAPPA | c.4499C>A p.S1500* | Nonsense Mutation (SNP) | VAF 32/138 reads (23%) | called by muse, mutect2, varscan2
- PARD3B | c.2731G>T p.E911* (on ENST00000406610 / NM_001302769.2; = p.E842* on NM_057177.7) | Nonsense Mutation (SNP) | VAF 50/441 reads (11%) | called by muse, mutect2, varscan2
- PCDH8 | c.3143G>T p.G1048V | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- PCDH9 | c.1832T>C p.I611T | Missense Mutation (SNP) | VAF 84/435 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PCDHA1 | c.1258G>T p.V420F | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- PCDHA4 | c.1273G>C p.V425L | Missense Mutation (SNP) | VAF 43/341 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- PCDHB13 | c.258G>T p.L86F | Missense Mutation (SNP) | VAF 48/840 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.065); called by muse, varscan2
- PCDHB6 | c.801T>A p.D267E | Missense Mutation (SNP) | VAF 70/466 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHB7 | c.1328A>T p.D443V | Missense Mutation (SNP) | VAF 77/541 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA12 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.515); called by muse, mutect2
- PCDHGB1 | c.2179C>A p.L727I | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- PCYT1A | c.411G>T p.Q137H | Missense Mutation (SNP) | VAF 131/740 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- PDE8B | c.331A>G p.S111G | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, varscan2
- PEAK1 | c.4215G>C p.W1405C | Missense Mutation (SNP) | VAF 119/691 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PLA2G6 | c.1867G>T p.A623S | Missense Mutation (SNP) | VAF 32/548 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.027); called by muse, mutect2
- PLCB4 | c.2083G>C p.V695L | Missense Mutation (SNP) | VAF 181/596 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- PLCH1 | c.1751A>G p.Q584R (on ENST00000340059 / NM_001130960.2; = p.Q596R on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 229/864 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- PLCH1 | c.1051C>A p.P351T (on ENST00000340059 / NM_001130960.2; = p.P363T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- PLEC | c.10429G>T p.D3477Y (on ENST00000322810 / NM_201380.4; = p.D3367Y on NM_000445.5) | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- PLOD1 | c.1650G>T p.T550= | Splice Region (SNP) | VAF 114/461 reads (25%) | called by muse, mutect2, varscan2
- PML | c.363G>T p.Q121H | Missense Mutation (SNP) | VAF 67/537 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- POLE | c.3146A>G p.Q1049R | Missense Mutation (SNP) | VAF 71/594 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- POLQ | c.7104G>C p.M2368I | Missense Mutation (SNP) | VAF 113/667 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- POR | c.1255T>A p.Y419N | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POTEJ | c.2535del p.R846Gfs*3 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, varscan2
- POU5F2 | c.880C>G p.L294V | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PPP1R42 | c.297-1G>T p.X99_splice | Splice Site (SNP) | VAF 18/127 reads (14%) | called by muse, mutect2, varscan2
- PPP1R9A | c.2893G>T p.D965Y | Missense Mutation (SNP) | VAF 162/714 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRDM5 | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 142/634 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PRR14L | c.4916G>T p.R1639L | Missense Mutation (SNP) | VAF 42/694 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.416); called by muse, mutect2
- PRR35 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- PRX | c.4241G>T p.R1414M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, varscan2
- PSG3 | c.1152T>G p.I384M | Missense Mutation (SNP) | VAF 156/770 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, varscan2
- PTPRD | c.1456A>T p.K486* | Nonsense Mutation (SNP) | VAF 93/405 reads (23%) | called by muse, mutect2, varscan2
- PTPRS | c.4099A>G p.M1367V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PXDN | c.4270G>C p.A1424P | Missense Mutation (SNP) | VAF 223/763 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PZP | c.2982C>A p.N994K | Missense Mutation (SNP) | VAF 65/397 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RAD54B | c.1032G>T p.Q344H | Missense Mutation (SNP) | VAF 109/552 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RBM11 | c.692G>T p.W231L | Missense Mutation (SNP) | VAF 204/720 reads (28%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.013); called by muse, varscan2
- RBM39 | c.404A>G p.K135R | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- RBMX | c.253A>T p.T85S | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RDH14 | c.122T>A p.M41K | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- RDX | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 133/633 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- RELN | c.304C>A p.Q102K | Missense Mutation (SNP) | VAF 182/890 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.893); called by muse, varscan2
- RESF1 | c.1807A>C p.N603H | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RIC8B | c.56A>T p.E19V | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.5); called by muse, mutect2
- RIMS1 | c.2636A>T p.Q879L | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- RUSC1 | c.2596C>T p.R866W (on ENST00000368352 / NM_001105203.2; = p.R397W on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- SAFB | c.1978G>C p.E660Q | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.796); called by muse, mutect2
- SAFB2 | c.1250C>A p.T417K | Missense Mutation (SNP) | VAF 24/363 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2
- SAMD9 | c.733G>T p.G245W | Missense Mutation (SNP) | VAF 77/418 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCN10A | c.458C>A p.P153Q | Missense Mutation (SNP) | VAF 73/337 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- SCN10A | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 73/335 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- SCN11A | c.1199C>T p.T400I | Missense Mutation (SNP) | VAF 174/687 reads (25%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SCNN1D | c.1229A>G p.Y410C (on ENST00000338555; = p.Y574C on NM_001130413.4) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SEL1L | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- SEM1 | c.12+2T>G p.X4_splice | Splice Site (SNP) | VAF 65/310 reads (21%) | called by mutect2, varscan2
- SH3TC2 | c.525_527del p.E176del | In Frame Del (DEL) | VAF 69/616 reads (11%) | called by mutect2, pindel, varscan2
- SLC15A5 | c.406T>C p.Y136H | Missense Mutation (SNP) | VAF 82/516 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.07); called by muse, mutect2
- SLC17A2 | c.1127C>A p.T376N | Missense Mutation (SNP) | VAF 52/309 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SLC25A23 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 62/347 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC34A1 | c.686T>A p.L229Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC35G5 | c.874G>C p.V292L | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SLC5A6 | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 74/471 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC8B1 | c.1381A>G p.T461A | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SLC8B1 | c.1245del p.R416Gfs*12 | Frame Shift Del (DEL) | VAF 33/140 reads (24%) | called by mutect2, pindel, varscan2
- SLITRK3 | c.1820T>C p.L607P | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.133); called by muse, mutect2
- SMARCA4 | c.3431A>T p.E1144V | Missense Mutation (SNP) | VAF 70/275 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- SMLR1 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 89/319 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- SNCAIP | c.1175C>A p.A392D | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SOCS6 | c.1312G>T p.G438C | Missense Mutation (SNP) | VAF 97/312 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SOX4 | c.232A>G p.M78V | Missense Mutation (SNP) | VAF 47/293 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- SP8 | c.41C>A p.P14Q (on ENST00000361443 / NM_198956.4; = p.P32Q on NM_182700.6) | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- SPATA31A6 | c.1616C>A p.P539H | Missense Mutation (SNP) | VAF 216/560 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SPATA31D1 | c.2369A>T p.E790V | Missense Mutation (SNP) | VAF 140/622 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SPOCK1 | c.279del p.H94Tfs*5 | Frame Shift Del (DEL) | VAF 21/201 reads (10%) | called by mutect2, pindel*, varscan2*
- SSX2 | c.488C>T p.A163V (on ENST00000337502 / NM_175698.2; = p.P212S on NM_003147.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/397 reads (18%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- TAOK2 | c.2137G>T p.E713* | Nonsense Mutation (SNP) | VAF 23/129 reads (18%) | called by muse, mutect2, varscan2
- TATDN3 | c.84G>T p.L28F | Missense Mutation (SNP) | VAF 94/304 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, varscan2
- TBK1 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 73/376 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- TBX15 | c.1286C>G p.T429S (on ENST00000369429 / NM_001330677.2; = p.T323S on NM_152380.3) | Missense Mutation (SNP) | VAF 192/644 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBX22 | c.1052C>A p.P351H | Missense Mutation (SNP) | VAF 118/385 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- TCF20 | c.2917G>T p.D973Y | Missense Mutation (SNP) | VAF 48/417 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- TECTA | c.530C>T p.T177I | Missense Mutation (SNP) | VAF 150/508 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- TENM3 | c.2674T>C p.Y892H | Missense Mutation (SNP) | VAF 75/328 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEP1 | c.6200G>T p.C2067F | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TESPA1 | c.481G>T p.A161S (on ENST00000316577 / NM_001098815.3; = p.A23S on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TEX15 | c.3+2T>A p.X1_splice | Splice Site (SNP) | VAF 81/341 reads (24%) | called by muse, mutect2, varscan2
- TEX44 | c.136T>A p.W46R | Missense Mutation (SNP) | VAF 63/539 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX51 | c.443G>T p.C148F (on ENST00000643416; = p.C124F on NM_001322244.2) | Missense Mutation (SNP) | VAF 70/316 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- THOC1 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 52/381 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- THSD7A | c.2585G>T p.G862V | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- THSD7A | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- TLX3 | c.556C>A p.H186N | Missense Mutation (SNP) | VAF 43/344 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- TNK2 | c.2870G>T p.R957L | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNXB | c.5582G>A p.R1861K (on ENST00000647633; = p.R1614K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/419 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- TP63 | c.2043A>T p.*681Cext*12 | Nonstop Mutation (SNP) | VAF 29/314 reads (9%) | called by muse, mutect2
- TPO | c.776G>A p.C259Y | Missense Mutation (SNP) | VAF 109/294 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAV20 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 106/447 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- TRIM3 | c.1668G>T p.W556C | Missense Mutation (SNP) | VAF 74/291 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIM33 | c.499G>T p.G167W | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TRIM51 | c.74C>A p.P25Q | Missense Mutation (SNP) | VAF 93/478 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM66 | c.3490G>T p.E1164* | Nonsense Mutation (SNP) | VAF 110/604 reads (18%) | called by muse, mutect2, varscan2
- TRIP13 | c.41G>T p.C14F | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); called by muse, mutect2
- TRPA1 | c.2356T>C p.C786R | Missense Mutation (SNP) | VAF 28/498 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- TRRAP | c.2803C>T p.L935F | Missense Mutation (SNP) | VAF 40/331 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRRAP | c.3998A>G p.K1333R | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); called by muse, mutect2
- TTN | c.43870C>T p.L14624F (on ENST00000591111; = p.L7200F on NM_003319.4) | Missense Mutation (SNP) | VAF 26/84 reads (31%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTPA | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); called by muse, varscan2
- UNC13C | c.6149dup p.D2051Gfs*12 | Frame Shift Ins (INS) | VAF 56/598 reads (9%) | called by mutect2, pindel
- UNC5D | c.1654G>C p.G552R | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- USH2A | c.6062_6088del p.G2021_A2029del | In Frame Del (DEL) | VAF 176/771 reads (23%) | called by mutect2, pindel
- USHBP1 | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VAMP2 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VCPIP1 | c.1338A>G p.I446M | Missense Mutation (SNP) | VAF 24/291 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- VGLL2 | c.723_741del p.L242Rfs*69 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | called by mutect2, pindel
- VPREB1 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 155/412 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, varscan2
- VPREB1 | c.228C>A p.D76E | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.39); called by muse, varscan2
- VSIG8 | c.483C>A p.N161K | Missense Mutation (SNP) | VAF 89/248 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- VWA3B | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 83/368 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- WDR72 | c.2372C>G p.T791R | Missense Mutation (SNP) | VAF 275/1209 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- WNT1 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- WT1 | c.1364A>G p.K455R | Missense Mutation (SNP) | VAF 108/801 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- WWP2 | c.505A>T p.S169C | Missense Mutation (SNP) | VAF 80/344 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- XDH | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 85/685 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XRN1 | c.2950G>T p.E984* | Nonsense Mutation (SNP) | VAF 76/460 reads (17%) | called by muse, varscan2
- XYLT1 | c.1430G>T p.R477L | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBED9 | c.824G>A p.R275K | Missense Mutation (SNP) | VAF 54/259 reads (21%) | SIFT tolerated, low confidence (0.49); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ZBTB1 | c.694G>C p.D232H | Missense Mutation (SNP) | VAF 79/479 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZFYVE26 | c.5818A>T p.I1940F | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ZFYVE26 | c.5816C>G p.A1939G | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.172); called by muse, mutect2
- ZNF275 | c.387G>T p.W129C | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- ZNF300 | c.437G>T p.R146M | Missense Mutation (SNP) | VAF 68/553 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ZNF438 | c.477G>T p.M159I | Missense Mutation (SNP) | VAF 67/239 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF443 | c.1561C>G p.R521G | Missense Mutation (SNP) | VAF 90/330 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- ZNF469 | c.3451G>T p.E1151* (on ENST00000437464; = p.E1179* on NM_001367624.2) | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- ZNF547 | c.26del p.X9_splice | Splice Site (DEL) | VAF 13/144 reads (9%) | called by pindel, varscan2
- ZNF883 | c.966G>T p.Q322H | Missense Mutation (SNP) | VAF 115/351 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- ZSCAN23 | c.225G>C p.Q75H | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZSWIM2 | c.623T>A p.L208* | Nonsense Mutation (SNP) | VAF 92/833 reads (11%) | called by muse, mutect2, varscan2
- AAK1 | c.2070A>T p.S690= | Silent (SNP) | VAF 52/602 reads (9%) | called by muse, mutect2
- ACAN | c.5385C>A p.L1795= | Silent (SNP) | VAF 89/768 reads (12%) | called by muse, mutect2, varscan2
- ACOT8 | c.276G>T p.L92= | Silent (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
- ACSS3 | c.663A>G p.T221= | Silent (SNP) | VAF 31/383 reads (8%) | called by muse, mutect2
- ADAM19 | c.2805C>A p.V935= | Silent (SNP) | VAF 25/219 reads (11%) | called by muse, mutect2, varscan2
- AK7 | c.159G>A p.E53= | Silent (SNP) | VAF 39/275 reads (14%) | called by muse, mutect2, varscan2
- ALG1 | c.834C>G p.A278= | Silent (SNP) | VAF 44/230 reads (19%) | called by muse, mutect2, varscan2
- ANO3 | c.2832C>T p.D944= | Silent (SNP) | VAF 127/553 reads (23%) | called by muse, mutect2, varscan2
- AOC1 | c.117A>G p.Q39= | Silent (SNP) | VAF 44/268 reads (16%) | catalogued as rs368128052; called by muse, mutect2, varscan2
- ARHGAP30 | c.2910G>C p.R970= (on ENST00000368013 / NM_001025598.2; = p.R759= on NM_181720.3) | Silent (SNP) | VAF 43/111 reads (39%) | called by muse, mutect2, varscan2
- ASNS | c.360G>T p.V120= | Silent (SNP) | VAF 50/592 reads (8%) | called by muse, mutect2
- ATP13A2 | c.1215G>T p.G405= | Silent (SNP) | VAF 50/176 reads (28%) | catalogued as rs763507619; called by mutect2, varscan2
- BCAS3 | c.2415A>G p.S805= (on ENST00000390652 / NM_001353144.2; = p.S790= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 89/453 reads (20%) | called by muse, mutect2, varscan2
- BRD9 | c.393A>C p.T131= | Silent (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- C1QTNF9 | c.723C>T p.F241= | Silent (SNP) | VAF 49/439 reads (11%) | catalogued as COSV59658210; called by muse, mutect2, varscan2
- C2CD6 | c.1233C>A p.G411= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as COSV53793383; called by mutect2, varscan2
- C3 | c.4902G>A p.E1634= | Silent (SNP) | VAF 36/315 reads (11%) | catalogued as rs749728116; called by muse, mutect2, varscan2
- CALHM3 | c.651C>T p.S217= | Silent (SNP) | VAF 47/234 reads (20%) | called by muse, varscan2
- CAPN7 | c.900A>T p.A300= | Silent (SNP) | VAF 78/370 reads (21%) | called by muse, mutect2, varscan2
- CATSPER2 | c.222A>T p.I74= | Silent (SNP) | VAF 134/613 reads (22%) | called by muse, mutect2, varscan2
- CD200R1 | c.966C>T p.L322= (on ENST00000471858 / NM_170780.3; = p.L345= on NM_138806.4) | Silent (SNP) | VAF 11/166 reads (7%) | called by muse, mutect2
- CDCA7 | c.726G>C p.V242= (on ENST00000347703 / NM_145810.3; = p.V321= on NM_031942.5) | Silent (SNP) | VAF 43/319 reads (13%) | called by muse, mutect2, varscan2
- CDH2 | c.2442C>A p.I814= | Silent (SNP) | VAF 71/509 reads (14%) | called by muse, mutect2, varscan2
- CEBPB | c.51G>T p.P17= | Silent (SNP) | VAF 74/295 reads (25%) | called by muse, varscan2
- CELSR3 | c.567G>A p.R189= | Silent (SNP) | VAF 56/235 reads (24%) | catalogued as COSV50898863; called by muse, mutect2, varscan2
- CEP44 | c.54C>T p.R18= | Silent (SNP) | VAF 64/306 reads (21%) | called by muse, mutect2, varscan2
- CFAP47 | c.2385C>A p.T795= | Silent (SNP) | VAF 50/132 reads (38%) | called by muse, mutect2, varscan2
- CHST13 | c.471C>T p.P157= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs1389594748; called by muse, mutect2, varscan2
- CIR1 | c.465G>T p.S155= | Silent (SNP) | VAF 188/833 reads (23%) | catalogued as COSV59595481; called by muse, mutect2, varscan2
- CLEC14A | c.159C>A p.A53= | Silent (SNP) | VAF 21/107 reads (20%) | called by muse, mutect2, varscan2
- COL2A1 | c.2646T>C p.G882= | Silent (SNP) | VAF 23/272 reads (8%) | called by muse, mutect2
- CPN2 | c.648G>T p.L216= | Silent (SNP) | VAF 95/535 reads (18%) | called by muse, mutect2, varscan2
- CRH | c.189G>C p.P63= | Silent (SNP) | VAF 22/248 reads (9%) | called by muse, mutect2
- DKKL1 | c.636C>G p.V212= | Silent (SNP) | VAF 21/189 reads (11%) | called by muse, mutect2, varscan2
- DNAJB11 | c.486G>A p.Q162= | Silent (SNP) | VAF 32/585 reads (5%) | catalogued as COSV99408598; called by muse, mutect2
- DTNBP1 | c.369G>C p.A123= | Silent (SNP) | VAF 192/928 reads (21%) | catalogued as COSV59038188; called by muse, mutect2, varscan2
- DYNC2H1 | c.2841A>G p.T947= | Silent (SNP) | VAF 129/496 reads (26%) | catalogued as rs182475949, COSV62105784; called by muse, mutect2, varscan2
- DYSF | c.5061T>C p.S1687= | Silent (SNP) | VAF 160/534 reads (30%) | called by muse, mutect2, varscan2
- EGR4 | c.276G>A p.A92= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV71532301; called by muse, mutect2, varscan2
- EIF2S3B | c.945T>C p.F315= | Silent (SNP) | VAF 35/242 reads (14%) | called by muse, mutect2, varscan2
- EIF5AL1 | c.330G>A p.E110= | Silent (SNP) | VAF 56/525 reads (11%) | called by muse, mutect2, varscan2
- ELANE | c.351C>T p.D117= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as COSV55048238; called by muse, varscan2
- ELN | c.1161C>A p.P387= | Silent (SNP) | VAF 101/490 reads (21%) | catalogued as CD101096; called by muse, mutect2, varscan2
- ETF1 | c.99C>T p.S33= | Silent (SNP) | VAF 31/175 reads (18%) | catalogued as COSV100860091; called by muse, mutect2, varscan2
- FAM90A10P | c.1149G>T p.A383= | Silent (SNP) | VAF 53/307 reads (17%) | called by muse, mutect2, varscan2
- FASN | c.4353G>T p.S1451= | Silent (SNP) | VAF 54/339 reads (16%) | called by muse, mutect2, varscan2
- FHOD3 | c.2922G>C p.T974= (on ENST00000359247 / NM_001281739.3; = p.T991= on NM_025135.5) | Silent (SNP) | VAF 105/462 reads (23%) | called by muse, mutect2, varscan2
- FUT4 | c.828G>C p.A276= | Silent (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- G6PC2 | c.312A>T p.T104= | Silent (SNP) | VAF 154/728 reads (21%) | called by muse, mutect2, varscan2
- GDA | c.267C>T p.S89= | Silent (SNP) | VAF 77/264 reads (29%) | catalogued as COSV52991088; called by muse, mutect2, varscan2
- GK5 | c.1236A>T p.S412= | Silent (SNP) | VAF 30/390 reads (8%) | called by muse, mutect2
- GLB1L3 | c.225G>T p.R75= | Silent (SNP) | VAF 40/118 reads (34%) | called by muse, mutect2, varscan2
- GLP1R | c.928C>A p.R310= | Silent (SNP) | VAF 67/295 reads (23%) | called by muse, mutect2, varscan2
- GUCA1C | c.249A>T p.L83= | Silent (SNP) | VAF 52/901 reads (6%) | called by muse, mutect2
- HCN1 | c.258G>T p.G86= | Silent (SNP) | VAF 76/311 reads (24%) | catalogued as COSV100298379; called by muse, mutect2, varscan2
- HECTD1 | c.4563G>A p.L1521= | Silent (SNP) | VAF 35/209 reads (17%) | called by muse, mutect2, varscan2
- HEPACAM | c.936C>A p.I312= | Silent (SNP) | VAF 50/650 reads (8%) | called by muse, mutect2
- HLA-DRA | c.442C>A p.R148= | Silent (SNP) | VAF 108/684 reads (16%) | catalogued as COSV66622958; called by muse, mutect2, varscan2
- IGF2BP2 | c.1257G>A p.P419= | Silent (SNP) | VAF 69/294 reads (23%) | catalogued as rs151111656; called by muse, mutect2, varscan2
- IGHV6-1 | c.81A>T p.S27= | Silent (SNP) | VAF 30/218 reads (14%) | called by muse, mutect2, varscan2
- IL1RAPL2 | c.417C>A p.G139= | Silent (SNP) | VAF 62/180 reads (34%) | called by muse, mutect2, varscan2
- ITGA2B | c.111G>T p.V37= | Silent (SNP) | VAF 70/287 reads (24%) | called by muse, mutect2, varscan2
- ITK | c.1845T>A p.I615= | Silent (SNP) | VAF 116/928 reads (13%) | called by muse, mutect2, varscan2
- KIF4B | c.1422C>A p.T474= | Silent (SNP) | VAF 36/349 reads (10%) | called by muse, mutect2, varscan2
- KIR3DL1 | c.1242T>A p.P414= | Silent (SNP) | VAF 95/390 reads (24%) | called by muse, mutect2, varscan2
- KLHDC7B | c.1089T>A p.R363= (on ENST00000395676; = p.R1004= on NM_138433.5) | Silent (SNP) | VAF 53/322 reads (16%) | called by muse, mutect2, varscan2
- KLRC1 | c.105A>G p.E35= | Silent (SNP) | VAF 61/363 reads (17%) | catalogued as rs1458482058; called by muse, mutect2, varscan2
- MAGEB4 | c.297A>T p.T99= | Silent (SNP) | VAF 59/157 reads (38%) | called by muse, mutect2, varscan2
- MAP2 | c.2811G>T p.A937= | Silent (SNP) | VAF 23/189 reads (12%) | catalogued as COSV52302430; called by muse, mutect2, varscan2
- MAST1 | c.1107G>T p.P369= | Silent (SNP) | VAF 15/135 reads (11%) | called by muse, mutect2, varscan2
- MRC2 | c.462C>G p.R154= | Silent (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2
- MTRNR2L6 | c.10C>A p.R4= | Silent (SNP) | VAF 42/296 reads (14%) | catalogued as COSV66579193; called by muse, varscan2
- MUC5B | c.13578C>A p.P4526= | Silent (SNP) | VAF 89/256 reads (35%) | catalogued as COSV71590692; called by muse, mutect2, varscan2
- MYH4 | c.1074C>A p.A358= | Silent (SNP) | VAF 69/329 reads (21%) | catalogued as COSV99700626; called by muse, mutect2, varscan2
- MYO16 | c.723C>A p.I241= | Silent (SNP) | VAF 64/407 reads (16%) | called by muse, mutect2, varscan2
- MYO16 | c.724C>T p.L242= | Silent (SNP) | VAF 64/404 reads (16%) | called by muse, mutect2, varscan2
- MYOZ2 | c.762T>C p.D254= | Silent (SNP) | VAF 95/275 reads (35%) | called by muse, mutect2, varscan2
- NIPAL3 | c.660C>T p.V220= | Silent (SNP) | VAF 41/180 reads (23%) | called by muse, mutect2, varscan2
- NLGN4X | c.1236G>T p.G412= | Silent (SNP) | VAF 58/190 reads (31%) | called by muse, mutect2, varscan2
- NLRP8 | c.1137C>G p.V379= | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as rs771329389; called by muse, mutect2, varscan2
- NPAS3 | c.2247C>A p.P749= (on ENST00000356141 / NM_001164749.2; = p.P717= on NM_022123.3) | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- NPSR1 | c.996C>A p.V332= | Silent (SNP) | VAF 34/240 reads (14%) | catalogued as COSV100706430; called by muse, mutect2, varscan2
- NRP2 | c.303G>T p.L101= | Silent (SNP) | VAF 44/548 reads (8%) | called by muse, mutect2
- NRXN1 | c.468G>T p.G156= | Silent (SNP) | VAF 24/195 reads (12%) | catalogued as COSV68004020; called by muse, mutect2, varscan2
- OBI1 | c.1146A>G p.E382= | Silent (SNP) | VAF 74/379 reads (20%) | called by muse, varscan2
- OLIG2 | c.903G>T p.P301= | Silent (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- OR10S1 | c.468A>C p.A156= | Silent (SNP) | VAF 81/428 reads (19%) | catalogued as rs769876254; called by muse, mutect2, varscan2
- OR10Z1 | c.555G>T p.L185= | Silent (SNP) | VAF 133/346 reads (38%) | catalogued as rs774546981, COSV63524339; called by muse, mutect2, varscan2
- OR4A16 | c.438C>A p.A146= | Silent (SNP) | VAF 98/627 reads (16%) | catalogued as COSV100125358; called by muse, mutect2, varscan2
- OR56A5 | c.99C>A p.P33= | Silent (SNP) | VAF 28/205 reads (14%) | called by mutect2, varscan2
- OR6C65 | c.855C>A p.P285= | Silent (SNP) | VAF 20/238 reads (8%) | called by muse, mutect2
- OR8B3 | c.609G>T p.V203= | Silent (SNP) | VAF 63/343 reads (18%) | called by muse, mutect2, varscan2
- OR8G1 | c.630C>A p.P210= | Silent (SNP) | VAF 12/384 reads (3%) | catalogued as COSV100422278; called by muse, mutect2
- PASK | c.2967G>A p.A989= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as rs201257680; called by muse, mutect2, varscan2
- PCDHA1 | c.1257G>T p.S419= | Silent (SNP) | VAF 30/188 reads (16%) | called by muse, mutect2, varscan2
- PCDHA3 | c.1749G>T p.R583= | Silent (SNP) | VAF 32/185 reads (17%) | called by muse, mutect2, varscan2
- PCDHA9 | c.1785C>T p.R595= | Silent (SNP) | VAF 26/207 reads (13%) | catalogued as COSV65324696; called by muse, mutect2, varscan2
- PCDHB5 | c.669C>A p.S223= | Silent (SNP) | VAF 33/275 reads (12%) | catalogued as COSV50648633, COSV99169477; called by muse, mutect2, varscan2
- PCF11 | c.2844A>T p.L948= | Silent (SNP) | VAF 203/668 reads (30%) | called by muse, mutect2, varscan2
- PDE2A | c.2325C>A p.R775= | Silent (SNP) | VAF 50/234 reads (21%) | called by muse, mutect2, varscan2
- PDE8B | c.330C>A p.T110= | Silent (SNP) | VAF 20/164 reads (12%) | called by muse, varscan2
- PDE8B | c.366C>A p.I122= | Silent (SNP) | VAF 145/1003 reads (14%) | called by muse, mutect2, varscan2
- PDE8B | c.2140C>A p.R714= | Silent (SNP) | VAF 85/752 reads (11%) | catalogued as COSV53740810; called by muse, mutect2, varscan2
- PFKM | c.1635A>G p.A545= | Silent (SNP) | VAF 120/689 reads (17%) | catalogued as rs1447012163; called by muse, mutect2, varscan2
- PHACTR2 | c.546G>T p.G182= | Silent (SNP) | VAF 96/444 reads (22%) | called by mutect2, varscan2
- PLCH1 | c.1176C>A p.I392= (on ENST00000340059 / NM_001130960.2; = p.I404= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/386 reads (12%) | catalogued as COSV58193253; called by muse, mutect2, varscan2
- PON1 | c.852C>T p.C284= | Silent (SNP) | VAF 157/692 reads (23%) | catalogued as rs775037874; called by muse, mutect2, varscan2
- PPM1E | c.1278C>A p.T426= | Silent (SNP) | VAF 53/195 reads (27%) | called by muse, mutect2, varscan2
- PROS1 | c.645T>A p.A215= | Silent (SNP) | VAF 36/446 reads (8%) | called by muse, mutect2
- PSG3 | c.1230A>G p.T410= | Silent (SNP) | VAF 72/329 reads (22%) | called by muse, varscan2
- RANGAP1 | c.345G>T p.V115= | Silent (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2, varscan2
- RAP1GAP2 | c.417C>T p.L139= | Silent (SNP) | VAF 41/176 reads (23%) | catalogued as COSV54582293, COSV54590931; called by muse, mutect2, varscan2
- RCSD1 | c.102C>A p.A34= | Silent (SNP) | VAF 54/160 reads (34%) | called by muse, mutect2, varscan2
- RHBDF1 | c.516G>T p.A172= | Silent (SNP) | VAF 32/211 reads (15%) | called by muse, mutect2, varscan2
- ROCK1 | c.4032A>G p.K1344= | Silent (SNP) | VAF 35/272 reads (13%) | called by muse, mutect2, varscan2
- RPH3A | c.1665G>A p.L555= (on ENST00000389385 / NM_001143854.2; = p.L551= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/238 reads (22%) | called by muse, mutect2, varscan2
- RREB1 | c.4458A>T p.S1486= | Silent (SNP) | VAF 43/299 reads (14%) | called by muse, mutect2, varscan2
- RYR3 | c.7194A>T p.L2398= (on ENST00000389232; = p.L2399= on NM_001036.6) | Silent (SNP) | VAF 31/309 reads (10%) | called by muse, mutect2, varscan2
- SAMD9 | c.4722G>T p.L1574= | Silent (SNP) | VAF 74/647 reads (11%) | called by muse, mutect2, varscan2
- SCN3A | c.3150C>A p.S1050= | Silent (SNP) | VAF 147/633 reads (23%) | called by muse, mutect2, varscan2
- SESN1 | c.876A>T p.A292= (on ENST00000356644 / NM_001199933.1; = p.A351= on NM_014454.3) | Silent (SNP) | VAF 123/498 reads (25%) | called by muse, mutect2, varscan2
- SGIP1 | c.1506G>T p.R502= | Silent (SNP) | VAF 125/542 reads (23%) | catalogued as COSV99392093; called by muse, mutect2, varscan2
- SLC13A2 | c.1173G>C p.L391= | Silent (SNP) | VAF 36/170 reads (21%) | called by muse, mutect2, varscan2
- SLC43A1 | c.804G>A p.L268= | Silent (SNP) | VAF 43/168 reads (26%) | catalogued as rs1443609500; called by mutect2, varscan2
- SLC6A18 | c.1686C>G p.L562= | Silent (SNP) | VAF 17/124 reads (14%) | catalogued as COSV57249908; called by muse, mutect2, varscan2
- SLC9A2 | c.885A>T p.I295= | Silent (SNP) | VAF 135/606 reads (22%) | called by muse, mutect2, varscan2
- SMLR1 | c.198G>T p.L66= | Silent (SNP) | VAF 88/319 reads (28%) | called by muse, mutect2, varscan2
- STARD9 | c.12918A>G p.R4306= | Silent (SNP) | VAF 39/169 reads (23%) | called by muse, mutect2, varscan2
- SYT14 | c.1299A>G p.S433= | Silent (SNP) | VAF 60/1188 reads (5%) | called by muse, mutect2
- TBL3 | c.747A>G p.P249= | Silent (SNP) | VAF 33/264 reads (13%) | called by muse, mutect2, varscan2
- TENM3 | c.1620G>A p.L540= | Silent (SNP) | VAF 69/264 reads (26%) | called by muse, mutect2, varscan2
- THSD7B | c.1704C>A p.A568= | Silent (SNP) | VAF 36/137 reads (26%) | called by muse, mutect2, varscan2
- TMEM131 | c.3069T>C p.N1023= | Silent (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- TMEM132E | c.762T>A p.G254= (on ENST00000321639; = p.G344= on NM_001304438.2) | Silent (SNP) | VAF 48/194 reads (25%) | called by muse, mutect2, varscan2
- TMEM63B | c.1776C>T p.L592= | Silent (SNP) | VAF 53/232 reads (23%) | called by muse, mutect2, varscan2
- TMEM67 | c.2850G>A p.V950= | Silent (SNP) | VAF 90/533 reads (17%) | called by muse, mutect2, varscan2
- TMIGD3 | c.447G>T p.T149= (on ENST00000369717 / NM_001081976.2; = p.T230= on NM_020683.7) | Silent (SNP) | VAF 76/378 reads (20%) | catalogued as COSV63163056; called by muse, mutect2, varscan2
- TNFSF14 | c.150G>T p.G50= | Silent (SNP) | VAF 68/271 reads (25%) | called by muse, mutect2, varscan2
- TP63 | c.432G>C p.T144= | Silent (SNP) | VAF 64/790 reads (8%) | catalogued as COSV53201611; called by muse, mutect2
- TRBC2 | c.426C>T p.V142= | Silent (SNP) | VAF 58/315 reads (18%) | catalogued as rs1554512943; called by muse, mutect2, varscan2
- TRIM43B | c.558G>T p.L186= | Silent (SNP) | VAF 46/562 reads (8%) | called by muse, mutect2, varscan2
- TRPM2 | c.3570C>A p.A1190= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs1310715717; called by muse, mutect2, varscan2
- TRRAP | c.186A>T p.L62= | Silent (SNP) | VAF 50/210 reads (24%) | called by muse, mutect2, varscan2
- TTC28 | c.1428A>G p.A476= | Silent (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- TUBB4A | c.933G>C p.L311= | Silent (SNP) | VAF 31/145 reads (21%) | called by muse, mutect2, varscan2
- UNC5D | c.1443C>T p.I481= | Silent (SNP) | VAF 59/276 reads (21%) | catalogued as rs1321679532; called by muse, varscan2
- UNC80 | c.4293T>C p.P1431= | Silent (SNP) | VAF 62/505 reads (12%) | catalogued as rs920689307; called by muse, mutect2, varscan2
- URB1 | c.6726G>A p.V2242= | Silent (SNP) | VAF 41/175 reads (23%) | catalogued as rs1316362619; called by muse, mutect2, varscan2
- USE1 | c.15G>A p.R5= | Silent (SNP) | VAF 33/133 reads (25%) | catalogued as rs371968820; called by muse, mutect2, varscan2
- VNN1 | c.330T>C p.N110= | Silent (SNP) | VAF 70/239 reads (29%) | called by muse, mutect2, varscan2
- VPS41 | c.2379G>T p.S793= | Silent (SNP) | VAF 116/557 reads (21%) | catalogued as rs146415083; called by muse, mutect2, varscan2
- XKR5 | c.1887G>T p.P629= | Silent (SNP) | VAF 58/191 reads (30%) | called by muse, mutect2, varscan2
- ZBTB20 | c.336G>T p.G112= (on ENST00000474710 / NM_001164342.2; = p.G39= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 34/260 reads (13%) | called by muse, mutect2, varscan2
- ZBTB40 | c.2580G>C p.G860= | Silent (SNP) | VAF 95/459 reads (21%) | called by muse, mutect2, varscan2
- ZNF208 | c.3168C>T p.P1056= | Silent (SNP) | VAF 40/682 reads (6%) | called by muse, mutect2
- ABCC8 | c.2694+21C>A | Intron (SNP) | VAF 28/151 reads (19%) | called by muse, mutect2, varscan2
- AC004890.2 | n.2192A>T | RNA (SNP) | VAF 60/218 reads (28%) | called by muse, mutect2, varscan2
- AC011503.1 | n.467+8648G>A | Intron (SNP) | VAF 22/183 reads (12%) | catalogued as rs1416833534; called by muse, mutect2, varscan2
- AC011525.1 | n.685G>T | RNA (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- AC024940.1 | n.4069T>A | RNA (SNP) | VAF 95/409 reads (23%) | called by muse, mutect2, varscan2
- AC084879.1 | n.1140T>A | RNA (SNP) | VAF 91/464 reads (20%) | called by muse, mutect2, varscan2
- AC084879.1 | n.1139T>A | RNA (SNP) | VAF 93/462 reads (20%) | called by muse, mutect2, varscan2
- AC092329.3 | c.-211-412C>G | Intron (SNP) | VAF 52/488 reads (11%) | called by muse, mutect2, varscan2
- AC097518.1 | n.78C>A | RNA (SNP) | VAF 97/319 reads (30%) | called by muse, mutect2, varscan2
- AC103993.1 | n.147G>A | RNA (SNP) | VAF 36/323 reads (11%) | called by muse, mutect2, varscan2
- AL583829.1 | n.468+7434del | Intron (DEL) | VAF 32/106 reads (30%) | called by mutect2, pindel, varscan2
- ALB | c.843+18T>C | Intron (SNP) | VAF 156/665 reads (23%) | catalogued as rs752630772; called by muse, mutect2, varscan2
- AP003062.1 | n.900G>T | RNA (SNP) | VAF 228/736 reads (31%) | called by muse, varscan2
- APBB1IP | c.453+59T>C | Intron (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- ARHGEF18 | c.-131C>G | 5'UTR (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- ATAD3B | c.*518del | 3'UTR (DEL) | VAF 41/134 reads (31%) | called by mutect2, pindel, varscan2
- ATP7B | c.-25A>G | 5'UTR (SNP) | VAF 103/591 reads (17%) | called by muse, mutect2, varscan2
- BHLHE23 | c.-10C>A | 5'UTR (SNP) | VAF 5/40 reads (13%) | catalogued as rs1008284633; called by muse, mutect2
- C1QTNF6 | c.289+796G>T | Intron (SNP) | VAF 42/327 reads (13%) | catalogued as rs542188315; called by muse, mutect2, varscan2
- C4A | chr6:32006374 G>C | 3'Flank (SNP) | VAF 98/517 reads (19%) | called by muse, mutect2, varscan2
- CCDC140 | n.714G>C | RNA (SNP) | VAF 42/177 reads (24%) | catalogued as rs776636015; called by muse, mutect2, varscan2
- CCDC162P | n.2046G>T | RNA (SNP) | VAF 106/378 reads (28%) | called by muse, mutect2, varscan2
- CCDC33 | chr15:74336336 G>T | 3'Flank (SNP) | VAF 13/120 reads (11%) | catalogued as rs1010529773; called by muse, mutect2, varscan2
- CD48 | c.652+93A>G | Intron (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- CDKL1 | c.367-740G>A | Intron (SNP) | VAF 35/332 reads (11%) | called by muse, mutect2, varscan2
- CLIP3 | c.*12A>T | 3'UTR (SNP) | VAF 61/297 reads (21%) | called by muse, mutect2, varscan2
- COILP1 | n.244G>A | RNA (SNP) | VAF 28/218 reads (13%) | catalogued as rs760360927; called by muse, mutect2, varscan2
- DBF4B | c.1189+581G>T | Intron (SNP) | VAF 34/223 reads (15%) | called by muse, mutect2, varscan2
- DGKB | c.2126-31283C>A | Intron (SNP) | VAF 102/422 reads (24%) | called by muse, mutect2, varscan2
- DNM1P34 | n.612C>T | RNA (SNP) | VAF 16/68 reads (24%) | called by mutect2, varscan2
- DPYS | c.*101C>T | 3'UTR (SNP) | VAF 115/553 reads (21%) | called by muse, mutect2, varscan2
- FAAP20 | chr1:2187191 G>T | 3'Flank (SNP) | VAF 86/274 reads (31%) | catalogued as rs1251352000; called by muse, mutect2, varscan2
- FAM182B | n.712G>T | RNA (SNP) | VAF 34/252 reads (13%) | catalogued as rs1417768011; called by muse, mutect2, varscan2
- FAM83D | chr20:38926416 C>A | 5'Flank (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- FBN2 | c.952+4168C>A | Intron (SNP) | VAF 48/472 reads (10%) | called by muse, mutect2, varscan2
- FRMD8P1 | n.582G>T | RNA (SNP) | VAF 69/190 reads (36%) | called by muse, mutect2, varscan2
- FUZ | c.-37A>G | 5'UTR (SNP) | VAF 46/381 reads (12%) | called by muse, mutect2, varscan2
- GABRA2 | c.1060-5654C>A | Intron (SNP) | VAF 55/195 reads (28%) | catalogued as COSV62919081; called by muse, mutect2, varscan2
- GCOM1 | c.1305-16775A>G | Intron (SNP) | VAF 19/151 reads (13%) | catalogued as rs1479057162; called by muse, mutect2, varscan2
- GP1BB | c.-3G>A | 5'UTR (SNP) | VAF 28/209 reads (13%) | catalogued as COSV100820472; called by muse, mutect2, varscan2
- GREM1 | c.-2+342G>T | Intron (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- GUCY2EP | n.896G>T | RNA (SNP) | VAF 24/76 reads (32%) | called by muse, varscan2
- GVINP1 | n.5656G>A | RNA (SNP) | VAF 40/273 reads (15%) | called by muse, mutect2, varscan2
- HAND2-AS1 | n.512+1123C>A | Intron (SNP) | VAF 16/105 reads (15%) | catalogued as rs886390244; called by muse, mutect2, varscan2
- HERC2 | c.801-18C>G | Intron (SNP) | VAF 18/442 reads (4%) | called by muse, mutect2
- HNF4G | c.-23-3751A>T | Intron (SNP) | VAF 52/248 reads (21%) | called by muse, mutect2, varscan2
- HOXD10 | c.-25T>A | 5'UTR (SNP) | VAF 33/293 reads (11%) | called by muse, mutect2, varscan2
- IGKV1-39 | c.-17C>A | 5'UTR (SNP) | VAF 51/430 reads (12%) | called by muse, mutect2, varscan2
- IKBIP | c.297+7780A>T | Intron (SNP) | VAF 48/199 reads (24%) | catalogued as rs376060492; called by muse, mutect2, varscan2
- IL16 | c.-159G>T | 5'UTR (SNP) | VAF 27/267 reads (10%) | called by muse, mutect2, varscan2
- ITK | c.986-30C>A | Intron (SNP) | VAF 78/592 reads (13%) | called by muse, mutect2, varscan2
- KDELR2 | c.-12G>T | 5'UTR (SNP) | VAF 23/88 reads (26%) | called by muse, mutect2, varscan2
- KNG1 | c.*1343T>C | 3'UTR (SNP) | VAF 76/560 reads (14%) | called by muse, mutect2, varscan2
- KRT18 | c.418-35A>T | Intron (SNP) | VAF 127/453 reads (28%) | called by muse, mutect2, varscan2
- LINC00303 | n.859G>A | RNA (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2, varscan2
- MIR1202 | n.5C>A | RNA (SNP) | VAF 84/350 reads (24%) | called by muse, mutect2, varscan2
- MIR20A | n.27G>T | RNA (SNP) | VAF 19/87 reads (22%) | catalogued as rs1260934034; called by muse, mutect2, varscan2
- MROH8 | c.109+2756G>T | Intron (SNP) | VAF 56/362 reads (15%) | called by muse, mutect2, varscan2
- MTCH1 | c.*23G>T | 3'UTR (SNP) | VAF 123/662 reads (19%) | catalogued as rs1010568918; called by muse, mutect2, varscan2
- MTCL1 | chr18:8831824 A>G | 3'Flank (SNP) | VAF 22/159 reads (14%) | called by muse, mutect2, varscan2
27 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 27 other) are not listed here.
